Surgical pathology report (de-identified scan), TCGA case TCGA-SI-AA8B, project TCGA-SARC (Sarcoma), tissue source site Washington University St. Louis, specimen TCGA-SI-AA8B-01A (Primary Tumor).

[page 1 of 3]
Patient Name: [REDACTED]
DOB: [REDACTED]

Surgical Pathology Report

Final

ICD O-3
Sarcoma, undifferentiated, pleomorphic
(8805/3) (8802/3)
Code to highest 8805/3
Site: L Thigh NOS C49.2
MD 6/30/14

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

Service: Orthopedic Surgery

Location: [REDACTED]

MRN: [REDACTED]

Hospital: [REDACTED]

Patient Type: [REDACTED]

Accession: [REDACTED]

Talent: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED]

DIAGNOSIS:

SKIN AND SOFT TISSUE, LEFT THIGH, WIDE EXCISION

- UNDIFFERENTIATED PLEOMORPHIC SARCOMA, 20.0 CM, GRADE 3 (SEE COMMENT AND SYNOPSIS)
- TUMOR IS FOCALLY PRESENT AT INKED RESECTION MARGIN
- DERMAL SCAR WITH POST SURGICAL CHANGES

LYMPH NODES, LEFT THIGH, EXCISION

- TWO LYMPH NODES, ONE WITH TUMOR BY DIRECT EXTENSION; NO EVIDENCE OF DISCONTINUOUS SPREAD (0/2) (SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides and/or other material indicated in the diagnosis.

***Report Electronically Reviewed and Signed Out By: [REDACTED]

Diagnosis Comment

Microscopic Description and Comment:

Sections of the tumor show a high grade sarcoma, characterized by spindle cells growing in a fascicular growth pattern alternating with areas with pleomorphic, polygonal and often multinucleated giant cells, with high mitotic counts and rare foci of necrosis. The findings, combined with the results of the prior consult case immunohistochemistry work up, are those of an undifferentiated pleomorphic sarcoma. Tumor has very high mitotic activity and focal necrosis so is grade 3 of 3

Tumor is focally present at black inked deep margin (block A12). The specimen was not oriented, but by landmarks may be able to be reconstructed and this site correlated with clinical findings, if this is deemed clinically necessary. In addition, two lymph nodes are found histologically directly adjacent to the tumor mass. One of them shows tumor growing up and around the periphery of it. The findings do not support lymphatic (discontinuous) metastasis. Thus, the tumor is still considered to be N0.

[page 2 of 3]
Patient Name: [REDACTED]

DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

History:

The patient is an [REDACTED]-year-old woman with a prior diagnosis of soft tissue sarcoma in the left thigh [REDACTED].
Operative procedure: Left proximal medial thigh mass wide excision.

Specimen(s) Received:

A: LEFT THIGH MASS

Gross Description:

The specimen is received in a formalin-filled container labeled with the patient's name [REDACTED] and "left thigh mass." It contains a 2600 gram, unoriented soft tissue mass with attached multiple fragments of skeletal muscle and an ellipse of skin. The soft tissue mass measures 20 x 14 x 12 cm and the skin ellipse measures 13 cm in length and 3 cm in width with underlying 2 cm thick fibroadipose tissue. A 3.5 cm long surgical scar is present in the middle portion of the skin ellipse, measuring 4 cm from one tip and 7.8 cm from the opposite tip. The tip that is closer to the surgical margin is now arbitrarily designated as 12 o'clock and the opposite tip as 6 o'clock. A 15 x 2.5 x 1.5 cm cylindrical-shaped fragment of skeletal muscle is present, attached to the 9 o'clock of the skin ellipse. In addition, a large irregularly shaped fragment of skeletal muscle is identified on the 3 o'clock of the skin ellipse, measuring 6 x 11 x 1.5 cm. Grossly, the entire mass has a pseudocapsule, that consists of smooth-shiny fibroconnective tissue. A fragment of skeletal muscle is present at the 6 o'clock tip of the entire specimen, measuring 7 x 10 cm. Inked as follows: 12 to 3 to 6 o'clock - blue; 6 to 9 to 12 o'clock - black. The specimen is sectioned to show a cystic and hemorrhagic cut surface with focal putative necrosis. Part of the cut surface show a pink-tan, fleshy and solid consistency. Portion of the cross section also show multiple numerous papillary excrescences, protruding into the cavity area. The tumor appears to be confined to the pseudocapsule but the closest distance between the solid area of tumor and ink measures less than 1 mm (at the 3 o'clock blue inked margin). Labeled A1 - cross section across the skin and scar; A2 - radial section of the tumor at 12 o'clock; A3 - additional radial section at 12 o'clock; A4 - cystic lesion in relation to the 3 o'clock muscle group; A5 - tumor in relation to the deep margin; A6 - tumor in relation to the closest blue inked 3 o'clock margin; A7 - tumor in relation to blue inked 3 o'clock deep margin; A8 - tumor in relation to the superficial subcutaneous tissue; A9 - tumor in relation to the black inked deep resection margin; A10 - tumor in relation to the 9 o'clock black inked deep margin; A11 - tumor in relation to the 9 o'clock black inked deep margin; A12 - cystic lesion in relation to 9 o'clock black inked deep margin; A13 - radial sections of the tumor in relation to the 6 o'clock black inked margin; A14 to A17 - additional tumor. Jar 4.

SYNOPTIC REPORTING FORM - SOFT TISSUE -- RESECTION FOR SARCOMA

TUMOR LOCATION

The tumor is located in the extremity and superficial trunk

HISTOPATHOLOGIC TYPE

The principal histologic pattern is undifferentiated pleomorphic sarcoma

HISTOLOGIC GRADE (G)

The lesion is poorly differentiated-High Grade (G3)
FNCLCC system Grade 3 of 3

SAMPLED SPECIMEN MARGINS

Tumor is focally present at inked margin (block A12)

PRIMARY TUMOR (T)

Tumor more than 5 cm in greatest dimension and deep (T2b)

[page 3 of 3]
Patient Name: [REDACTED]

DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis (N0)

The total number of involved lymph nodes is 0

The total number of nodes examined histologically is 2
see comment

DISTANT METASTASES (M)

Distant metastasis cannot be assessed (MX)

STAGE GROUPING

T2b/N0/MX/G3 (Stage III)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Surgical Pathology report is available on-line on

Prior incisional biopsy.

END OF REPORT

Page 3 of 3

Page: 3 of 3

Printed from

Source: NCI Genomic Data Commons file 9fc30aff-d3e5-4eeb-bf41-da90ec7e3f51 (TCGA-SI-AA8B.A8171830-B139-4F58-907B-EA944BE0FAE9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).